Somatic mutation profile of tumor specimen TARGET-10-PASILW-09A (aliquot TARGET-10-PASILW-09A-01D) from TARGET case TARGET-10-PASILW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.4 years (4,535 days).
Specimen TARGET-10-PASILW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe7c28ce-2364-44f7-a20d-5e50e2cd9c3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASILW-10A (Blood Derived Normal), aliquot TARGET-10-PASILW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12a06437-fa06-408b-8c2c-82ccfee1ed23

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, RNA 2, Intron 1, 5'UTR 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMD2 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.028); catalogued as rs948008887, COSV68660649; called by muse, mutect2, varscan2
- MPDZ | c.2364+1G>A p.X788_splice | Splice Site (SNP) | VAF 23/41 reads (56%) | catalogued as rs767669471, COSV59941891; called by muse, mutect2, varscan2
- NOTCH1 | c.7382del p.S2461Tfs*16 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | catalogued as COSV53052798; called by mutect2, pindel, varscan2
- PTEN | c.750_751delinsGGCCGTTTGA p.C250Wfs*4 | Nonsense Mutation (INS) | VAF 26/80 reads (33%) | catalogued as COSV64288359; called by pindel, varscan2*
- PTEN | c.770dup p.F258Lfs*40 | Frame Shift Ins (INS) | VAF 31/72 reads (43%) | catalogued as COSV64299060; called by pindel, varscan2
- ST6GALNAC6 | c.269A>C p.D90A | Missense Mutation (SNP) | VAF 28/52 reads (54%) | PolyPhen benign (0.116); catalogued as COSV52535577; called by muse, mutect2, varscan2
- ATXN1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2
- SUPT20HL2 | c.1788G>T p.Q596H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- AGRN | c.2142C>A p.G714= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV65072289; called by muse, mutect2, varscan2
- FAM122A | c.732T>C p.L244= | Silent (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- GPR137 | c.654G>A p.A218= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs376129341; called by muse, mutect2, varscan2
- PCLO | c.12432T>A p.G4144= | Silent (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- FAM81B | c.294-7769G>T | Intron (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- FOXP3 | c.*21G>A | 3'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs781902934; called by muse, mutect2
- GCM2 | c.-116_-115insA | 5'UTR (INS) | VAF 7/17 reads (41%) | called by mutect2, varscan2
- MUC20P1 | n.831T>C | RNA (SNP) | VAF 3/12 reads (25%) | catalogued as rs28461405; called by mutect2, varscan2
- PRPF4BP1 | n.315C>G | RNA (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
